Gene-level copy-number profile of tumor specimen TCGA-K1-A3PN-02A from TCGA case TCGA-K1-A3PN, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 64.7 years (23,631 days).
Specimen TCGA-K1-A3PN-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.1e1caf9c-70f1-4184-8ee2-871bd9ac81dc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K1-A3PN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/098a3079-14cd-4933-8cdf-b42c89463cad

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 10; copy number 2: 10,449; copy number 3: 326; copy number 4: 46,770; copy number 5: 159; copy number 6: 1,372; copy number 7: 2; copy number 8: 118; copy number 9: 3; copy number 20: 3; copy number 24: 491.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K1-A3PN-02A-11D-A227-01): tumor purity 0.94, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–4): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr19:47,019,837–47,113,776, 3 genes (within-gene range 0–2): NPAS1, TMEM160, ZC3H4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 494 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:9,021,510–22,706,703, 494 genes, copy number 20–24 (within-gene range 2–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
